Somatic mutation profile of tumor specimen TCGA-55-A48Z-01A (aliquot TCGA-55-A48Z-01A-12D-A24P-08) from TCGA case TCGA-55-A48Z, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 60.4 years (22,056 days).
Specimen TCGA-55-A48Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a333057b-c1ad-4963-96b8-3652204c3dbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-A48Z-10A (Blood Derived Normal), aliquot TCGA-55-A48Z-10A-01D-A24P-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/70684d97-4512-4674-ae09-1854b97f7923

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 16 silent.
By variant classification: Missense Mutation 35, Silent 16, Splice Site 3, Nonsense Mutation 3, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2156G>C p.G719A | Missense Mutation (SNP) | VAF 35/126 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs121913428, COSV51769339, COSV51771914, COSV51779524; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- RB1 | c.940-1G>T p.X314_splice | Splice Site (SNP) | VAF 10/50 reads (20%) | catalogued as rs1131690860, COSV57298214, COSV57321122; ClinVar: likely pathogenic; called by muse, mutect2
- TP53 | c.1009C>T p.R337C | Missense Mutation (SNP) | VAF 14/36 reads (39%) | hotspot (GDC flag); SIFT tolerated (0.09); PolyPhen benign (0.344); catalogued as rs587782529, CM981929, COSV52669243, COSV52718762, COSV52810068, COSV52816817; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AP3B2 | c.2974C>A p.Q992K (on ENST00000261722; = p.Q986K on NM_004644.5) | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.536); catalogued as COSV55616053, COSV99916413; called by muse, mutect2, varscan2
- ASXL3 | c.4085C>A p.P1362Q | Missense Mutation (SNP) | VAF 30/173 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.347); catalogued as COSV99324666; called by muse, mutect2, varscan2
- BDP1 | c.2749G>C p.E917Q | Missense Mutation (SNP) | VAF 7/138 reads (5%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.848); catalogued as COSV100702994; called by muse, mutect2
- CLEC1A | c.478G>T p.D160Y | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.934); catalogued as COSV100191395; called by muse, mutect2, varscan2
- COL4A5 | c.1316C>A p.P439H | Missense Mutation (SNP) | VAF 12/171 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV100087503; called by muse, mutect2
- CWF19L2 | c.1256G>A p.W419* | Nonsense Mutation (SNP) | VAF 19/155 reads (12%) | catalogued as COSV56513549, COSV99978885; called by muse, mutect2, varscan2
- DGKK | c.3263T>G p.L1088R | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101052973; called by muse, mutect2, varscan2
- ERBB4 | c.1716+1G>T p.X572_splice | Splice Site (SNP) | VAF 14/102 reads (14%) | catalogued as COSV53600743; called by muse, mutect2, varscan2
- GSK3A | c.901A>G p.I301V | Missense Mutation (SNP) | VAF 26/83 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.807); catalogued as COSV99725226; called by muse, mutect2, varscan2
- HSPH1 | c.2246A>C p.K749T | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV100184868; called by muse, mutect2, varscan2
- IL7R | c.1334A>C p.Q445P | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT tolerated (0.06); PolyPhen benign (0.105); catalogued as COSV100286245; called by muse, mutect2, varscan2
- KCNK15 | c.776G>T p.R259L | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.313); catalogued as COSV100865112; called by muse, mutect2
- KCNQ3 | c.1932G>A p.M644I | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as COSV101195986; called by muse, mutect2
- MAP3K13 | c.700G>T p.E234* | Nonsense Mutation (SNP) | VAF 29/118 reads (25%) | catalogued as COSV53992128, COSV99407002; called by muse, mutect2, varscan2
- NFATC1 | c.2009G>A p.S670N | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.18); catalogued as COSV99501435; called by muse, mutect2, varscan2
- NIPBL | c.1424C>A p.A475D | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV99240188; called by muse, mutect2
- NOX3 | c.1595T>A p.V532E | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99343045; called by muse, mutect2, varscan2
- OBSL1 | c.4859C>T p.A1620V | Missense Mutation (SNP) | VAF 7/77 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.012); catalogued as COSV99522810; called by muse, mutect2
- OR11L1 | c.34T>G p.F12V | Missense Mutation (SNP) | VAF 12/96 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63315942; called by muse, mutect2, varscan2
- PCDH12 | c.3089T>A p.L1030Q | Missense Mutation (SNP) | VAF 35/221 reads (16%) | SIFT tolerated (0.17); PolyPhen benign (0.177); catalogued as COSV99187767; called by muse, mutect2, varscan2
- PLXNA3 | c.4834C>T p.R1612C | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782446260, COSV100859927; called by muse, mutect2, varscan2
- PRAMEF19 | c.997C>T p.R333C | Missense Mutation (SNP) | VAF 71/438 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.571); catalogued as rs781720759; called by muse, mutect2, varscan2
- RP1 | c.2884G>A p.G962R | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as COSV99607236; called by muse, mutect2, varscan2
- SERPINB8 | c.337C>T p.Q113* | Nonsense Mutation (SNP) | VAF 13/159 reads (8%) | catalogued as COSV54640847, COSV99729105; called by muse, mutect2
- SIGLEC10 | c.1060G>A p.A354T | Missense Mutation (SNP) | VAF 44/187 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.618); catalogued as rs145933557; called by muse, mutect2, varscan2
- SLC35F2 | c.380G>A p.R127K | Missense Mutation (SNP) | VAF 46/151 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99758602; called by muse, mutect2, varscan2
- SMARCA4 | c.3898G>A p.E1300K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1555785006, COSV100758454; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPAG16 | c.1594-1G>A p.X532_splice | Splice Site (SNP) | VAF 10/65 reads (15%) | catalogued as COSV100532154; called by muse, mutect2, varscan2
- TASOR2 | c.470G>T p.R157L | Missense Mutation (SNP) | VAF 9/94 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as COSV100050397, COSV60167947; called by muse, mutect2, varscan2
- TBC1D2 | c.2087G>C p.R696P | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100579861; called by muse, mutect2, varscan2
- TGM1 | c.1028C>G p.S343C | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV99252956; called by muse, mutect2, varscan2
- TRIO | c.8344G>A p.D2782N | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.253); catalogued as COSV100702548; called by muse, mutect2, varscan2
- TRRAP | c.7469T>C p.F2490S (on ENST00000359863 / NM_001244580.1; = p.F2472S on NM_003496.3) | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.856); catalogued as COSV100722404; called by muse, mutect2, varscan2
- VGLL4 | c.406A>T p.T136S | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV99809601; called by muse, mutect2
- VPS13B | c.8407A>G p.K2803E | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV100661801; called by muse, mutect2
- WDFY3 | c.2069G>T p.C690F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.333); catalogued as COSV99883222; called by muse, mutect2, varscan2
- WNK1 | c.2978C>A p.T993K | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV100267174; called by muse, mutect2, varscan2
- ZNF106 | c.2245C>T p.P749S | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55515451, COSV99782498; called by muse, mutect2, varscan2
- TMEM63B | c.1547_1554del p.H516Lfs*28 | Frame Shift Del (DEL) | VAF 22/74 reads (30%) | called by mutect2, pindel
- ADCY8 | c.3558G>T p.L1186= | Silent (SNP) | VAF 21/151 reads (14%) | catalogued as COSV53911706, COSV99651914; called by muse, mutect2, varscan2
- AUTS2 | c.921C>T p.P307= | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV100716354; called by muse, mutect2
- CCDC74B | c.747C>A p.G249= | Silent (SNP) | VAF 18/187 reads (10%) | catalogued as COSV60103273; called by muse, mutect2, varscan2
- CPAMD8 | c.522C>T p.G174= (on ENST00000651564; = p.G127= on NM_015692.5) | Silent (SNP) | VAF 23/133 reads (17%) | catalogued as rs368974759, COSV99359415; called by muse, mutect2, varscan2
- DNMT1 | c.3384C>T p.S1128= | Silent (SNP) | VAF 21/83 reads (25%) | catalogued as rs564054594, COSV100532370; called by muse, mutect2, varscan2
- DOCK9 | c.1302G>A p.A434= (on ENST00000376460 / NM_001366676.2; = p.A435= on NM_015296.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as rs1265110527, COSV59637131; called by muse, mutect2, varscan2
- ERCC6 | c.4215A>G p.L1405= | Silent (SNP) | VAF 19/145 reads (13%) | catalogued as COSV100875887; called by muse, mutect2, varscan2
- FLNA | c.3258C>T p.A1086= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV100774635; called by muse, mutect2, varscan2
- KCNH8 | c.2301C>T p.I767= | Silent (SNP) | VAF 31/102 reads (30%) | catalogued as rs1462895322, COSV100109561, COSV60455676; called by muse, mutect2, varscan2
- KTI12 | c.147C>T p.Y49= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV100860186; called by muse, mutect2
- OR52N5 | c.183G>A p.E61= | Silent (SNP) | VAF 20/144 reads (14%) | catalogued as COSV100399676; called by muse, mutect2, varscan2
- PTPRN | c.783C>T p.Y261= | Silent (SNP) | VAF 12/47 reads (26%) | catalogued as rs549588185, COSV55352002; called by muse, mutect2, varscan2
- PTPRZ1 | c.2431C>T p.L811= | Silent (SNP) | VAF 30/238 reads (13%) | catalogued as COSV66430931; called by muse, mutect2, varscan2
- RHBDF1 | c.1728C>T p.C576= | Silent (SNP) | VAF 11/60 reads (18%) | catalogued as rs200966432, COSV99244566; called by muse, mutect2
- SOCS5 | c.637T>C p.L213= | Silent (SNP) | VAF 30/116 reads (26%) | catalogued as COSV100125218; called by muse, mutect2, varscan2
- ZNF667 | c.1116C>A p.T372= | Silent (SNP) | VAF 18/77 reads (23%) | catalogued as rs371009489, COSV99410328; called by muse, mutect2, varscan2
